Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3939, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3939-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with a colon and cecal carcinoma characterized histologically as a moderately differentiated, colorectal adenocarcinoma, measuring 3 cm in diameter at the widest point. Invasive spread of the tumor within all intestinal wall layers up to the bordering mesocolic fatty tissue.

Aborally to Bauhin's valve, ascending colon with a tubular adenoma measuring 2.3 cm with moderate epithelial dysplasia (synonym: low-grade intraepithelial neoplasia).

An isolated section of the appendix displays enduring, slightly florid, chronic appendicitis and distinctive, enduring periappendicitis with resorptive xanthous tissue reaction, clearly as a result of a tumor-related relocation of the appendix ostium. The subserosa of the cecum and the oral section of the ascending colon have evidently progressive and extensive macrophage-rich inflammation in the context of perityphlitis.

The stage of tumor is therefore: pT3, pN0, (0/40) L0 V0; G2 R0

Source: NCI Genomic Data Commons file c923b5bf-cbaa-4dd4-ac33-2bd8c26228d1 (TCGA-AA-3939.4A1C0305-9B03-4B34-8F88-B535DB869F12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).